Gene-level copy-number profile of tumor specimen ALCH-B1O2-TTP1-A from ALCHEMIST case ALCH-B1O2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,734 days).
Specimen ALCH-B1O2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9b181930-0aff-40a6-a659-c5652ca9a7bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1O2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/a7061c79-0e88-4545-ba0c-95aa6f021c94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 283; copy number 1: 9,797; copy number 2: 47,452; copy number 3: 1,322; copy number 4: 20; copy number 5: 10; copy number 6: 9; copy number 7: 1; copy number 8: 1; copy number 14: 1; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 271 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,700,970, 3 genes (within-gene range 0–1): AL359881.3, AL359881.2, AL359881.1.
- chr1:15,792,796–15,793,285, 1 gene: RPL12P14.
- chr2:23,385,179–23,708,611, 4 genes (within-gene range 0–2): KLHL29, AC011239.1, AC011239.2, AC009242.1.
- chr2:95,274,449–95,386,077, 3 genes (within-gene range 0–2): PROM2, KCNIP3, FABP7P2.
- chr2:230,864,639–230,904,693, 2 genes: ITM2C, GCSIR.
- chr2:232,343,116–232,548,115, 15 genes (within-gene range 0–3): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG.
- chr3:50,279,087–50,312,381, 5 genes: LSMEM2, IFRD2, HYAL3, NAA80, HYAL1.
- chr4:8,745,391–8,871,839, 3 genes: AC209005.1, HMX1, AC116612.1.
- chr5:139,644,460–139,844,466, 9 genes: AC113361.1, CXXC5, CXXC5-AS1, AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2.
- chr5:181,147,586–181,205,293, 5 genes: OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1.
- chr7:5,274,369–5,513,809, 10 genes: SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr7:128,830,406–128,910,719, 5 genes (within-gene range 0–2): FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr7:151,190,873–151,227,205, 4 genes: IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2.
- chr9:33,441,156–33,473,930, 4 genes: AQP3, AL356218.1, NOL6, MIR6851.
- chr9:123,402,525–123,485,622, 2 genes (within-gene range 0–2): MIR601, MIR7150.
- chr10:43,077,064–43,138,334, 2 genes: RET, AC010864.1.
- chr11:47,331,406–47,449,143, 7 genes: MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–2): OTUB1.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr11:70,467,856–71,524,107, 16 genes (within-gene range 0–2): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2.
- chr11:72,615,063–72,621,827, 2 genes (within-gene range 0–1): MIR139, RNU7-105P.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr12:31,105,105–31,106,830, 1 gene: AC008013.3.
- chr15:25,176,832–25,257,027, 42 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:41,774,434–41,894,053, 8 genes (within-gene range 0–3): MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:83,899,115–83,966,332, 3 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1.
- chr16:89,873,570–90,019,890, 10 genes (within-gene range 0–1): TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:2,689,386–3,037,741, 9 genes (within-gene range 0–2): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:16,342,534–16,492,193, 13 genes (within-gene range 0–2): CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:30,550,493–30,790,908, 18 genes (within-gene range 0–2): AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8.
- chr17:36,601,583–36,634,698, 2 genes: MRM1, AC243830.2.
- chr17:63,432,304–63,548,977, 6 genes: CYB561, AC005828.5, ACE, AC113554.1, ACE3P, KCNH6.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:56,087,366–56,197,920, 7 genes: ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B.
- chr20:32,561,093–32,608,893, 2 genes (within-gene range 0–2): AL133343.2, NOL4L-DT.
- chr21:43,461,960–43,479,534, 2 genes (within-gene range 0–14): LINC00313, AP001048.1.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–1): AC016026.1, AC016026.2.
- chr22:19,714,503–19,724,772, 3 genes (within-gene range 0–1): SEPTIN5, AC000093.1, GP1BB.
- chr22:29,711,820–29,767,011, 4 genes (within-gene range 0–3): AC004882.2, CABP7, ZMAT5, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,113,639–1,153,726, 4 genes, copy number 6: AC092535.4, TMED11P, AC092535.1, AC092535.2.
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr7:74,650,231–74,789,376, 4 genes, copy number 6–17: GTF2I, AC211433.1, PHBP15, NCF1.
- chr8:143,734,139–143,790,645, 2 genes, copy number 5 (within-gene range 2–5): IQANK1, AC105219.3.
- chr8:143,816,344–143,832,861, 2 genes, copy number 5: PUF60, AC234917.3.
- chr9:136,738,167–136,766,255, 3 genes, copy number 6–7: LCN10, LCN8, LCN15.
- chr19:55,769,118–55,778,900, 2 genes, copy number 5: RFPL4AL1, RFPL4AP1.
- chr21:43,446,601–43,453,902, 1 gene, copy number 14: LINC00319.
- chr22:20,320,739–20,354,387, 4 genes, copy number 5–8 (within-gene range 2–8): AC007663.3, FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 6,953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
